Somatic mutation profile of cancer-model specimen HCM-SANG-0307-C15-85A (3D Organoid; aliquot HCM-SANG-0307-C15-85A-01D-A79N-36), derived from the primary tumor of HCMI case HCM-SANG-0307-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G2.
Specimen HCM-SANG-0307-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21e1f1c2-8515-4f3b-b40c-36a957ffb6c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0307-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0307-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1eb18a32-2fff-442f-bff5-b6b40047dbba

The open-access MAF lists 394 somatic variants for this specimen: 299 protein-altering or splice-affecting, 81 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 81, Intron 8, Frame Shift Del 6, Frame Shift Ins 6, Nonsense Mutation 6, In Frame Del 5, RNA 3, Splice Region 2, 5'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.3620A>C p.K1207T | Missense Mutation (SNP) | VAF 90/208 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV99271993; called by muse, mutect2, varscan2
- ADGB | c.461T>G p.I154S | Missense Mutation (SNP) | VAF 118/348 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV58865620; called by muse, mutect2, varscan2
- ALG13 | c.410A>G p.K137R | Missense Mutation (SNP) | VAF 121/121 reads (100%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1393707241; called by muse, mutect2, varscan2
- AP3B2 | c.1876T>A p.S626T | Missense Mutation (SNP) | VAF 167/327 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0.255); catalogued as COSV55605967; called by muse, mutect2, varscan2
- AQP4 | c.341A>C p.K114T | Missense Mutation (SNP) | VAF 174/522 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV67219745; called by muse, mutect2, varscan2
- ARFGEF2 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 179/388 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV64211831, COSV64212304; called by muse, mutect2, varscan2
- BRINP2 | c.1673A>T p.K558M | Missense Mutation (SNP) | VAF 100/469 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100838438, COSV100838572; called by muse, mutect2, varscan2
- C8orf48 | c.290A>C p.N97T | Missense Mutation (SNP) | VAF 117/3328 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as COSV52047801; called by muse, mutect2
- CACNA1D | c.5771A>C p.N1924T (on ENST00000350061 / NM_001128840.3; = p.N1944T on NM_000720.4) | Missense Mutation (SNP) | VAF 153/379 reads (40%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.277); catalogued as rs752740909; called by muse, mutect2, varscan2
- CACNA1E | c.1422A>C p.K474N | Missense Mutation (SNP) | VAF 89/427 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100704413; called by muse, mutect2, varscan2
- CACNG5 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 227/342 reads (66%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1333562967, COSV50055154; called by muse, mutect2, varscan2
- CDH11 | c.1815C>G p.N605K | Missense Mutation (SNP) | VAF 176/353 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.2); catalogued as COSV51755698; called by muse, varscan2
- CDX4 | c.346T>G p.L116V | Missense Mutation (SNP) | VAF 239/240 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.14); catalogued as rs1397674801; called by muse, mutect2, varscan2
- CFH | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 184/236 reads (78%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.753); catalogued as rs1332043837, COSV100809094; called by muse, mutect2, varscan2
- COL7A1 | c.912A>T p.Q304H | Missense Mutation (SNP) | VAF 118/364 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV100094466; called by muse, mutect2, varscan2
- COL7A1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 158/583 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs966257558, CX095173, COSV60394266; called by muse, mutect2, varscan2
- DAPK1 | c.4000T>G p.L1334V | Missense Mutation (SNP) | VAF 190/565 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs879749139, COSV63786825; called by muse, mutect2, varscan2
- DBH | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 296/481 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1348610910, COSV55040968; called by muse, mutect2, varscan2
- DCAF4 | c.579A>C p.K193N | Missense Mutation (SNP) | VAF 130/567 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs373154341; called by muse, mutect2, varscan2
- DLL4 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 134/278 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs761536904, COSV51063552; called by muse, mutect2, varscan2
- DNAH7 | c.10373T>G p.L3458R | Missense Mutation (SNP) | VAF 97/449 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56761441, COSV56769921; called by muse, mutect2, varscan2
- EDA2R | c.326A>C p.K109T | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99490833; called by muse, mutect2, varscan2
- EFNA4 | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 90/231 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99665036; called by muse, mutect2, varscan2
- EPB42 | c.1636G>A p.G546S (on ENST00000441366 / NM_001114134.2; = p.G576S on NM_000119.3) | Missense Mutation (SNP) | VAF 137/258 reads (53%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs369068948; ClinVar: uncertain significance; called by muse, varscan2
- ERC2 | c.1352T>G p.L451R | Missense Mutation (SNP) | VAF 130/411 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as rs184223678; called by muse, mutect2, varscan2
- FAM102A | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 142/498 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs372554454, COSV55948986; called by muse, mutect2, varscan2
- FAM135B | c.1682A>C p.K561T | Missense Mutation (SNP) | VAF 144/757 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as rs368544496; called by muse, mutect2, varscan2
- FAM227B | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 107/213 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs1278715716; called by muse, mutect2, varscan2
- FOXG1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 95/339 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1046668279, CD113880; ClinVar: likely benign; called by muse, mutect2, varscan2
- FOXJ1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 182/693 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs199916934; called by muse, mutect2, varscan2
- FSTL5 | c.416A>C p.K139T | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV60183600, COSV60210915; called by muse, mutect2, varscan2
- GREB1L | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 179/267 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs1339047723, COSV52549715, COSV52561552; called by muse, mutect2, varscan2
- GRM1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 112/310 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV51138888; called by muse, mutect2, varscan2
- GZMB | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 353/740 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376486286; called by muse, mutect2, varscan2
- H3C12 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 125/422 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs766861086, COSV58152693; called by muse, mutect2, varscan2
- HCFC1 | c.4563G>T p.Q1521H | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1557113061; called by muse, mutect2, varscan2
- IFNAR1 | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 186/187 reads (99%) | SIFT tolerated (0.79); PolyPhen benign (0.08); catalogued as rs199515722; called by muse, mutect2, varscan2
- IL2RA | c.417T>G p.I139M | Missense Mutation (SNP) | VAF 121/222 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as rs751445826, COSV56922426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IL36B | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV52086369, COSV52086934; called by muse, mutect2, varscan2
- IQSEC3 | c.1676C>A p.A559D (on ENST00000538872 / NM_001170738.2; = p.A256D on NM_015232.1) | Missense Mutation (SNP) | VAF 200/782 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.036); catalogued as rs1555088031; called by muse, varscan2
- IRS1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 358/790 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs771146954; called by muse, mutect2
- KCNQ5 | c.1258A>C p.S420R | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV59662086, COSV59665050; called by muse, mutect2, varscan2
- KCNT2 | c.3381A>T p.Q1127H | Missense Mutation (SNP) | VAF 207/261 reads (79%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.192); catalogued as COSV99657642; called by muse, mutect2, varscan2
- KIF5C | c.349T>G p.F117V | Missense Mutation (SNP) | VAF 139/405 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69170556; called by muse, mutect2, varscan2
- KMT2C | c.13597C>T p.R4533* | Nonsense Mutation (SNP) | VAF 318/320 reads (99%) | catalogued as COSV51471125; called by muse, mutect2, varscan2
- LINGO3 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 488/742 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as rs746504285; called by muse, mutect2, varscan2
- LOXHD1 | c.1988A>G p.K663R | Missense Mutation (SNP) | VAF 108/109 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.121); catalogued as rs1404938895; called by muse, mutect2, varscan2
- LRFN5 | c.706A>G p.S236G | Missense Mutation (SNP) | VAF 287/539 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV53247525, COSV53257646; called by muse, mutect2, varscan2
- LRRC4C | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 164/303 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776146097, COSV53424696; called by muse, mutect2, varscan2
- LRRC9 | c.3720A>C p.Q1240H | Missense Mutation (SNP) | VAF 91/416 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV99580792; called by muse, mutect2, varscan2
- MAG | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 386/557 reads (69%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs142036180; called by muse, mutect2, varscan2
- MDGA2 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 342/718 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs1376418244; called by muse, mutect2, varscan2
- MINDY4 | c.446T>G p.L149R | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.23); catalogued as COSV99518912; called by muse, mutect2, varscan2
- MN1 | c.3716C>T p.A1239V | Missense Mutation (SNP) | VAF 175/348 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1216829399; called by muse, mutect2, varscan2
- MTMR8 | c.164T>A p.I55N | Missense Mutation (SNP) | VAF 136/136 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66395262; called by muse, mutect2, varscan2
- MUC16 | c.39517T>G p.F13173V | Missense Mutation (SNP) | VAF 72/244 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66696637; called by muse, mutect2, varscan2
- MUC16 | c.26717C>T p.T8906I | Missense Mutation (SNP) | VAF 137/377 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV67456477; called by muse, mutect2, varscan2
- NBEA | c.1321A>T p.S441C | Missense Mutation (SNP) | VAF 108/325 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV59781310; called by muse, mutect2, varscan2
- NHLRC3 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 86/255 reads (34%) | catalogued as rs143048352; called by muse, mutect2, varscan2
- NLRP9 | c.2066T>A p.L689H | Missense Mutation (SNP) | VAF 144/398 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV104410031; called by muse, mutect2, varscan2
- NRG1 | c.1133A>G p.N378S (on ENST00000405005 / NM_013964.5; = p.N383S on NM_013956.5) | Missense Mutation (SNP) | VAF 119/230 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV55178387; called by muse, mutect2, varscan2
- OR10K2 | c.266A>T p.K89M | Missense Mutation (SNP) | VAF 151/391 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as COSV59221524; called by muse, mutect2, varscan2
- OR2T4 | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 322/431 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63544465, COSV63544829; called by muse, mutect2, varscan2
- OR4S2 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 124/298 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs142336485; called by muse, mutect2, varscan2
- OR52H1 | c.644T>C p.L215P (on ENST00000322653; = p.L221P on NM_001005289.1) | Missense Mutation (SNP) | VAF 131/247 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59505862; called by muse, mutect2, varscan2
- OR52N1 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 122/243 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as COSV57692824; called by muse, mutect2, varscan2
- OR56A1 | c.286A>G p.S96G | Missense Mutation (SNP) | VAF 121/264 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs1177639613, COSV57363127; called by muse, varscan2
- OR6C74 | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as COSV100667759, COSV59606389; called by muse, mutect2, varscan2
- PCDHB13 | c.2320T>A p.F774I | Missense Mutation (SNP) | VAF 126/360 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV53399467; called by muse, mutect2, varscan2
- PCDHB7 | c.2056G>A p.V686I | Missense Mutation (SNP) | VAF 491/2278 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.012); catalogued as rs200672237, COSV50753849; called by muse, mutect2, varscan2
- PCLO | c.6760G>A p.D2254N | Missense Mutation (SNP) | VAF 108/344 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.109); catalogued as rs1402428469, COSV61646063; called by muse, mutect2, varscan2
- PCLO | c.6038A>G p.E2013G | Missense Mutation (SNP) | VAF 235/354 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV61617911, COSV61620298; called by muse, mutect2, varscan2
- PLPPR3 | c.1344_1364del p.D448_E454del (on ENST00000520876 / NM_001270366.2; = p.D476_E482del on NM_024888.2) | In Frame Del (DEL) | VAF 294/606 reads (49%) | catalogued as rs767242232; called by mutect2, varscan2
- PNLIPRP3 | c.72G>T p.R24S | Missense Mutation (SNP) | VAF 139/259 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as rs1172007828; called by muse, mutect2, varscan2
- POC1B | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 199/200 reads (100%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as COSV100544510; called by muse, mutect2, varscan2
- POM121L12 | c.335T>C p.L112P | Missense Mutation (SNP) | VAF 251/730 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.542); catalogued as COSV68692948; called by muse, mutect2, varscan2
- PON3 | c.493A>C p.S165R | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as rs376520907; called by muse, mutect2, varscan2
- POTEC | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 213/216 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs878887288, COSV62802455; called by muse, mutect2
- POU2F3 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 143/249 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.055); catalogued as COSV52792918; called by muse, mutect2, varscan2
- PPP4R3C | c.1618A>G p.R540G | Missense Mutation (SNP) | VAF 125/126 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV69081024; called by muse, mutect2, varscan2
- PSMD1 | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 237/503 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs375200885; called by muse, mutect2, varscan2
- PTPRD | c.1564T>G p.F522V | Missense Mutation (SNP) | VAF 90/90 reads (100%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.931); catalogued as COSV61956668; called by muse, mutect2, varscan2
- PTPRT | c.1886A>C p.K629T | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV100628599; called by muse, mutect2, varscan2
- PZP | c.4300A>C p.S1434R | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV54353742; called by muse, mutect2, varscan2
- RP1 | c.1261A>T p.S421C | Missense Mutation (SNP) | VAF 91/335 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1440127138, COSV104377679; called by muse, mutect2, varscan2
- SERPINA6 | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 407/809 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58583792; called by muse, mutect2, varscan2
- SI | c.3538A>C p.T1180P | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV52266457; called by muse, mutect2, varscan2
- SIGLEC5 | c.1318G>C p.A440P | Missense Mutation (SNP) | VAF 43/419 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99707690; called by muse, mutect2, varscan2
- SLC7A13 | c.372dup p.P125Sfs*10 | Frame Shift Ins (INS) | VAF 136/582 reads (23%) | catalogued as rs761897892; called by mutect2, varscan2
- SLCO1C1 | c.584T>G p.L195R | Missense Mutation (SNP) | VAF 244/547 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56876854; called by muse, mutect2, varscan2
- SMARCC1 | c.2473A>C p.S825R | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.317); catalogued as rs1559631109; called by muse, mutect2, varscan2
- STAB1 | c.6475C>T p.R2159C | Missense Mutation (SNP) | VAF 233/359 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs373427616; called by muse, mutect2, varscan2
- TMEM132D | c.1571T>C p.L524P | Missense Mutation (SNP) | VAF 182/403 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101242540; called by muse, mutect2, varscan2
- TMX4 | c.185del p.P62Hfs*30 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | catalogued as COSV55679547; called by mutect2, pindel
- TNK2 | c.1522dup p.Q508Pfs*12 | Frame Shift Ins (INS) | VAF 162/266 reads (61%) | catalogued as rs754147115; called by mutect2, varscan2
- TRIM64B | c.1217T>A p.V406D | Missense Mutation (SNP) | VAF 175/686 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61693568; called by muse, mutect2, varscan2
- TTN | c.21526G>A p.A7176T (on ENST00000591111; = p.A6249T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/343 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV60169100; called by muse, mutect2, varscan2
- ZBTB41 | c.1747A>G p.S583G | Missense Mutation (SNP) | VAF 88/250 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100963544, COSV66358813; called by muse, mutect2, varscan2
- ZDBF2 | c.3598A>C p.S1200R | Missense Mutation (SNP) | VAF 129/570 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV65623359; called by muse, mutect2, varscan2
- ZFYVE1 | c.63T>G p.S21R | Missense Mutation (SNP) | VAF 164/565 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.06); catalogued as COSV59611396; called by muse, mutect2, varscan2
- ZNF474 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 146/290 reads (50%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.464); catalogued as COSV56945715; called by muse, mutect2, varscan2
- ZNF586 | c.749T>G p.I250S | Missense Mutation (SNP) | VAF 140/400 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV101197624; called by muse, mutect2, varscan2
- ZNF598 | c.2160C>G p.S720R | Missense Mutation (SNP) | VAF 160/331 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs911256482; called by muse, mutect2, varscan2
- ZNF667 | c.967A>C p.S323R | Missense Mutation (SNP) | VAF 150/429 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs1342030706; called by muse, mutect2, varscan2
- ZNF727 | c.496A>C p.I166L | Missense Mutation (SNP) | VAF 197/332 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.384); catalogued as COSV70701943; called by muse, mutect2, varscan2
- AATK | c.890T>G p.I297S (on ENST00000326724 / NM_001080395.3; = p.I194S on NM_004920.2) | Missense Mutation (SNP) | VAF 193/740 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ABCA13 | c.4347_4351del p.S1450Kfs*17 | Frame Shift Del (DEL) | VAF 26/240 reads (11%) | called by mutect2, pindel, varscan2
- ABCC9 | c.1058T>G p.V353G | Missense Mutation (SNP) | VAF 87/465 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ACP4 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 132/360 reads (37%) | called by muse, mutect2, varscan2
- ADCY2 | c.1460A>C p.K487T | Missense Mutation (SNP) | VAF 181/400 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ADCY8 | c.3413T>C p.L1138P | Missense Mutation (SNP) | VAF 144/807 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ADCY8 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 184/999 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ADGRD1 | c.2267A>G p.K756R | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ADGRE2 | c.692A>C p.N231T | Missense Mutation (SNP) | VAF 77/510 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ADHFE1 | c.371A>C p.E124A | Missense Mutation (SNP) | VAF 78/237 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AFF2 | c.1856A>T p.E619V | Missense Mutation (SNP) | VAF 171/171 reads (100%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- AFF2 | c.2245A>C p.I749L | Missense Mutation (SNP) | VAF 228/228 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AHNAK2 | c.8198A>G p.K2733R | Missense Mutation (SNP) | VAF 192/802 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AHNAK2 | c.7143A>C p.Q2381H | Missense Mutation (SNP) | VAF 203/846 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- AL451007.3 | c.207del p.R69Sfs*116 | Frame Shift Del (DEL) | VAF 69/684 reads (10%) | called by mutect2, pindel, varscan2
- ARHGAP26 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 139/423 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGDIA | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 143/639 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ARID4A | c.1961A>T p.D654V | Missense Mutation (SNP) | VAF 101/412 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ASIC5 | c.206T>G p.V69G | Missense Mutation (SNP) | VAF 209/389 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- ATP13A4 | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ATP7B | c.652A>G p.S218G | Missense Mutation (SNP) | VAF 97/306 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- BICD1 | c.2644A>G p.R882G | Missense Mutation (SNP) | VAF 146/627 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C19orf81 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 144/454 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- C2orf69 | c.702A>C p.K234N | Missense Mutation (SNP) | VAF 128/503 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAMSAP1 | c.3890A>C p.K1297T | Missense Mutation (SNP) | VAF 214/673 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC105 | c.1152A>C p.K384N | Missense Mutation (SNP) | VAF 149/420 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- CCDC146 | c.46A>T p.K16* | Nonsense Mutation (SNP) | VAF 65/292 reads (22%) | called by muse, mutect2, varscan2
- CCDC168 | c.19331A>C p.N6444T | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CCDC168 | c.11809G>T p.A3937S | Missense Mutation (SNP) | VAF 255/377 reads (68%) | SIFT tolerated (0.53); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CCDC184 | c.5A>C p.E2A | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC60 | c.209T>G p.F70C | Missense Mutation (SNP) | VAF 86/225 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CDH23 | c.6131A>C p.E2044A | Missense Mutation (SNP) | VAF 194/359 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- CERK | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CERS6 | c.83_103del p.E28_Q34del | In Frame Del (DEL) | VAF 80/465 reads (17%) | called by mutect2, pindel, varscan2
- CFTR | c.2651T>G p.L884R | Missense Mutation (SNP) | VAF 119/277 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CLCA4 | c.1409T>G p.I470S | Missense Mutation (SNP) | VAF 97/189 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CMYA5 | c.1866A>C p.E622D | Missense Mutation (SNP) | VAF 159/303 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP3 | c.1592A>T p.Q531L | Missense Mutation (SNP) | VAF 88/391 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- COL24A1 | c.1966T>G p.F656V | Missense Mutation (SNP) | VAF 168/169 reads (99%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- CRYBA4 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 136/290 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- CSAD | c.1043A>G p.D348G (on ENST00000444623 / NM_001244705.2; = p.D375G on NM_015989.5) | Missense Mutation (SNP) | VAF 218/394 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.7640A>T p.K2547M (on ENST00000520002; = p.K2546M on NM_033225.6) | Missense Mutation (SNP) | VAF 105/105 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- CSMD2 | c.2395A>C p.T799P | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CTSG | c.733T>G p.F245V | Missense Mutation (SNP) | VAF 100/454 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- CYB5R1 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 123/396 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- DMXL1 | c.4947A>C p.K1649N | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH11 | c.8234T>G p.V2745G | Missense Mutation (SNP) | VAF 194/313 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- DNAH14 | c.5265A>C p.K1755N (on ENST00000445597; = p.K2160N on NM_001367479.1) | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- DOCK3 | c.292A>C p.S98R | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DOP1A | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 146/455 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- DPP10 | c.1953T>G p.G651= | Splice Region (SNP) | VAF 42/162 reads (26%) | called by muse, mutect2, varscan2
- DUOX2 | c.3662C>T p.T1221I | Missense Mutation (SNP) | VAF 143/313 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- EBLN2 | c.32T>G p.V11G | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ECH1 | c.892A>G p.N298D | Missense Mutation (SNP) | VAF 109/230 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN3 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 174/788 reads (22%) | called by muse, mutect2, varscan2
- ENTPD3 | c.809A>C p.K270T | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- EXOC3L1 | c.2108T>A p.L703Q | Missense Mutation (SNP) | VAF 271/556 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FAM181B | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 201/338 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT4 | c.10449G>C p.L3483F | Missense Mutation (SNP) | VAF 13/361 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2
- FCGR1A | c.105A>T p.Q35H | Missense Mutation (SNP) | VAF 157/437 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- FRMD4B | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 130/426 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.051); called by muse, mutect2
- FRMPD2 | c.3365A>G p.E1122G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- GALNT5 | c.2471C>A p.S824Y | Missense Mutation (SNP) | VAF 70/251 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GLI2 | c.1889A>C p.K630T (on ENST00000361492 / NM_001374353.1; = p.K647T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 143/376 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GOLGA8F | c.509A>T p.K170M (on ENST00000526619; = p.K376M on NM_001350920.2) | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- GPR179 | c.4013C>A p.P1338H (on ENST00000621958; = p.P1337H on NM_001004334.4) | Missense Mutation (SNP) | VAF 244/743 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- GPR180 | c.776T>G p.L259R | Missense Mutation (SNP) | VAF 122/360 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GRIA1 | c.2505A>C p.E835D | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HIKESHI | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HMCES | c.86_89delinsG p.L29_P30delinsR | In Frame Del (DEL) | VAF 47/518 reads (9%) | called by pindel, varscan2*
- HMCN1 | c.16553A>G p.K5518R | Missense Mutation (SNP) | VAF 79/197 reads (40%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HMGB4 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 15/402 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2
- IGKV1-12 | c.98T>A p.V33E | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IL36A | c.136T>G p.L46V | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- IRAK1 | c.1340T>G p.V447G | Missense Mutation (SNP) | VAF 212/213 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- KANSL3 | c.374A>C p.E125A | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- KBTBD3 | c.1743A>C p.E581D | Missense Mutation (SNP) | VAF 109/262 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH7 | c.2011T>A p.S671T | Missense Mutation (SNP) | VAF 109/354 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- KCNJ5 | c.962_970del p.S321_D324delinsY | In Frame Del (DEL) | VAF 32/348 reads (9%) | called by mutect2, pindel
- KCNV1 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 324/550 reads (59%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- KIF27 | c.2519A>G p.E840G | Missense Mutation (SNP) | VAF 150/459 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KLRC1 | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 92/445 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- KRTAP25-1 | c.187T>G p.F63V | Missense Mutation (SNP) | VAF 120/266 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- LGALS3BP | c.203A>G p.E68G | Missense Mutation (SNP) | VAF 151/644 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LMO7 | c.979A>C p.S327R (on ENST00000357063; = p.S342R on NM_005358.5) | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LRP1B | c.13423dup p.T4475Nfs*3 | Frame Shift Ins (INS) | VAF 25/152 reads (16%) | called by mutect2, pindel, varscan2
- LRP1B | c.1236A>C p.Q412H | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP2 | c.12745T>G p.F4249V | Missense Mutation (SNP) | VAF 124/375 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- LRP2 | c.1561G>T p.V521F | Missense Mutation (SNP) | VAF 181/283 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- LRRC10B | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 261/543 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LYST | c.1634A>T p.E545V | Missense Mutation (SNP) | VAF 238/293 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- MAGEL2 | c.2789dup p.S931Lfs*3 | Frame Shift Ins (INS) | VAF 178/424 reads (42%) | called by mutect2, pindel, varscan2
- MCC | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 166/321 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MDN1 | c.16706T>C p.L5569P | Missense Mutation (SNP) | VAF 145/403 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MED12L | c.4162A>C p.S1388R | Missense Mutation (SNP) | VAF 74/281 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MED13 | c.4970A>C p.N1657T | Missense Mutation (SNP) | VAF 134/483 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MICU1 | c.330A>C p.K110N | Missense Mutation (SNP) | VAF 78/152 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- MKRN3 | c.32A>G p.H11R | Missense Mutation (SNP) | VAF 163/313 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MOBP | c.464A>G p.K155R (on ENST00000420739; = p.K179R on NM_001278322.2) | Missense Mutation (SNP) | VAF 255/690 reads (37%) | PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MRPS2 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 158/518 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MSN | c.782A>T p.D261V | Missense Mutation (SNP) | VAF 112/113 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- MTNR1B | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 220/381 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC16 | c.23902A>C p.T7968P | Missense Mutation (SNP) | VAF 145/489 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MUC16 | c.1448T>A p.L483H | Missense Mutation (SNP) | VAF 171/503 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYO5A | c.998T>G p.L333R | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCKAP1L | c.2999T>G p.L1000R | Missense Mutation (SNP) | VAF 106/234 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCKAP5 | c.2513C>G p.A838G | Missense Mutation (SNP) | VAF 125/345 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NCS1 | c.251A>C p.E84A | Missense Mutation (SNP) | VAF 131/400 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NEBL | c.2284A>G p.S762G | Missense Mutation (SNP) | VAF 99/207 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- NEXMIF | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NGDN | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 105/454 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP14 | c.2219A>C p.D740A | Missense Mutation (SNP) | VAF 126/289 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NRXN3 | c.2684T>G p.L895R (on ENST00000335750 / NM_001330195.2; = p.L522R on NM_004796.6) | Missense Mutation (SNP) | VAF 111/522 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NUFIP1 | c.1463A>T p.N488I | Missense Mutation (SNP) | VAF 171/300 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OR14C36 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OR4L1 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 166/487 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR4N2 | c.44T>G p.L15R | Missense Mutation (SNP) | VAF 116/705 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- OR4P4 | c.476T>G p.L159R | Missense Mutation (SNP) | VAF 162/312 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OR5D14 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 148/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR8B4 | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 148/278 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); called by muse, mutect2
- ORAI3 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 27/516 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PAK1 | c.683del p.N228Tfs*8 | Frame Shift Del (DEL) | VAF 37/272 reads (14%) | called by mutect2, pindel, varscan2
- PCDHA9 | c.962A>C p.E321A | Missense Mutation (SNP) | VAF 186/435 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PCDHA9 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 336/514 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PCNX3 | c.4237G>A p.E1413K | Missense Mutation (SNP) | VAF 120/238 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PDE1C | c.1718A>C p.K573T | Missense Mutation (SNP) | VAF 140/319 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PFN4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 188/293 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PIEZO2 | c.5764T>A p.S1922T | Missense Mutation (SNP) | VAF 172/522 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- PIGO | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 178/745 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG1 | c.1208A>G p.D403G | Missense Mutation (SNP) | VAF 96/279 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- POTEM | c.37T>G p.S13A | Missense Mutation (SNP) | VAF 101/583 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, varscan2
- POTEM | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRC2C | c.1791A>T p.K597N (on ENST00000367742; = p.K595N on NM_015172.4) | Missense Mutation (SNP) | VAF 93/264 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRRT1B | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 222/609 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PSMF1 | c.310T>G p.L104V | Missense Mutation (SNP) | VAF 141/313 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PTPRG | c.3930A>C p.E1310D | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- RAPH1 | c.3242_3243del p.E1081Afs*7 | Frame Shift Del (DEL) | VAF 228/672 reads (34%) | called by pindel, varscan2
- RBFOX1 | c.1136T>A p.L379H | Missense Mutation (SNP) | VAF 172/362 reads (48%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- RFPL4A | c.69A>C p.Q23H | Missense Mutation (SNP) | VAF 114/473 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS22 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 164/792 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- RHOBTB2 | c.596del p.V199Afs*102 | Frame Shift Del (DEL) | VAF 42/424 reads (10%) | called by mutect2, pindel, varscan2
- RNF144A | c.548A>T p.K183M | Missense Mutation (SNP) | VAF 208/326 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ROBO1 | c.3528A>C p.K1176N | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RUFY2 | c.478T>G p.L160V | Missense Mutation (SNP) | VAF 97/179 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RYR2 | c.5136C>A p.S1712R | Missense Mutation (SNP) | VAF 324/413 reads (78%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SCN11A | c.358A>C p.S120R | Missense Mutation (SNP) | VAF 111/298 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN2A | c.2478T>G p.F826L | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SCN7A | c.386T>G p.L129R | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEMA5A | c.1463A>T p.Q488L | Missense Mutation (SNP) | VAF 124/224 reads (55%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINA3 | c.704A>G p.K235R | Missense Mutation (SNP) | VAF 157/674 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, varscan2
- SFRP4 | c.674A>G p.K225R | Missense Mutation (SNP) | VAF 145/309 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SHD | c.612_613insA p.W205Mfs*64 | Frame Shift Ins (INS) | VAF 50/416 reads (12%) | called by mutect2, pindel, varscan2
- SIPA1L2 | c.1704A>C p.E568D | Missense Mutation (SNP) | VAF 110/322 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- SLAIN1 | c.1187A>C p.N396T (on ENST00000466548; = p.N133T on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC17A2 | c.920A>C p.N307T | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SLCO1B1 | c.349T>G p.F117V | Missense Mutation (SNP) | VAF 173/317 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SNTG2 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 44/655 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- SNW1 | c.269dup p.D91Gfs*3 | Frame Shift Ins (INS) | VAF 126/598 reads (21%) | called by mutect2, pindel, varscan2
- SP140 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 104/473 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SPARC | c.578A>C p.K193T | Missense Mutation (SNP) | VAF 109/302 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SPATA16 | c.868T>A p.Y290N | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- SPEG | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 156/681 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRBD1 | c.2075A>C p.K692T | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SREBF1 | c.2516A>C p.Y839S | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- STBD1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- TBC1D2 | c.1870G>T p.A624S | Missense Mutation (SNP) | VAF 196/557 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBL1XR1 | c.1200T>G p.S400R | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TBX2 | c.1318G>T p.A440S | Missense Mutation (SNP) | VAF 74/884 reads (8%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2
- THRB | c.1315T>G p.F439V | Missense Mutation (SNP) | VAF 111/409 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- TIGD4 | c.607A>C p.T203P | Missense Mutation (SNP) | VAF 133/266 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TMEM64 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 136/594 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53 | c.858_881del p.E287_E294del | In Frame Del (DEL) | VAF 263/280 reads (94%) | called by mutect2, pindel, varscan2
- TRAPPC2B | c.244A>G p.R82G | Missense Mutation (SNP) | VAF 174/536 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIP11 | c.561A>C p.E187D | Missense Mutation (SNP) | VAF 118/477 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- TRPA1 | c.612A>T p.Q204H | Missense Mutation (SNP) | VAF 286/411 reads (70%) | SIFT tolerated (0.57); PolyPhen benign (0.438); called by muse, mutect2
- TRPA1 | c.530A>G p.N177S | Missense Mutation (SNP) | VAF 223/293 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPC7 | c.919A>G p.S307G | Missense Mutation (SNP) | VAF 138/468 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRPM6 | c.2423A>G p.E808G | Missense Mutation (SNP) | VAF 119/376 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- TSHZ3 | c.1742A>G p.E581G | Missense Mutation (SNP) | VAF 195/541 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR2 | c.101T>C p.L34P | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- USF2 | c.941T>G p.L314R | Missense Mutation (SNP) | VAF 213/691 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP17L7 | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 118/284 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- VANGL2 | c.872T>G p.L291R | Missense Mutation (SNP) | VAF 151/413 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- VPS13B | c.1428A>G p.E476= | Splice Region (SNP) | VAF 61/305 reads (20%) | called by muse, mutect2, varscan2
- VSX2 | c.86G>A p.C29Y | Missense Mutation (SNP) | VAF 54/868 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.496); called by muse, mutect2
- XIRP1 | c.347A>G p.E116G | Missense Mutation (SNP) | VAF 181/512 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- ZFP28 | c.1304T>G p.L435R | Missense Mutation (SNP) | VAF 223/353 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZIK1 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 187/571 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ZIK1 | c.1325A>G p.K442R | Missense Mutation (SNP) | VAF 182/543 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ZIM3 | c.1202T>G p.F401C | Missense Mutation (SNP) | VAF 259/397 reads (65%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ZNF419 | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 173/486 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); called by mutect2, varscan2
- ZNF665 | c.374A>C p.N125T (on ENST00000600412; = p.N190T on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 251/413 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF763 | c.910A>T p.R304* (on ENST00000358987 / NM_001367172.2; = p.R307* on NM_001012753.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 138/419 reads (33%) | called by muse, mutect2, varscan2
- ZNF804B | c.2167A>G p.R723G | Missense Mutation (SNP) | VAF 121/528 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ADAMTS16 | c.2445T>G p.T815= | Silent (SNP) | VAF 117/250 reads (47%) | catalogued as COSV56976480, COSV56976826; called by muse, mutect2, varscan2
- AKAP3 | c.1194A>G p.Q398= | Silent (SNP) | VAF 180/635 reads (28%) | called by muse, mutect2, varscan2
- AMER3 | c.1878T>G p.T626= | Silent (SNP) | VAF 130/471 reads (28%) | called by mutect2, varscan2
- BAAT | c.870G>A p.L290= | Silent (SNP) | VAF 368/598 reads (62%) | called by muse, mutect2, varscan2
- CCDC39 | c.1635A>G p.K545= | Silent (SNP) | VAF 65/247 reads (26%) | called by muse, mutect2, varscan2
- CFAP44 | c.588T>A p.T196= | Silent (SNP) | VAF 83/227 reads (37%) | catalogued as COSV55616071; called by muse, mutect2, varscan2
- COBL | c.3102G>A p.R1034= | Silent (SNP) | VAF 403/595 reads (68%) | catalogued as rs764853569; called by muse, mutect2, varscan2
- CT55 | c.168G>T p.S56= | Silent (SNP) | VAF 178/180 reads (99%) | catalogued as COSV52278464; called by muse, mutect2, varscan2
- CUBN | c.4044A>T p.G1348= | Silent (SNP) | VAF 130/216 reads (60%) | called by muse, mutect2, varscan2
- CUL7 | c.3177G>A p.E1059= | Silent (SNP) | VAF 102/340 reads (30%) | called by muse, mutect2, varscan2
- CXADR | c.864G>A p.T288= | Silent (SNP) | VAF 115/227 reads (51%) | catalogued as rs145951623; called by muse, mutect2, varscan2
- CYP1B1 | c.1206C>T p.A402= | Silent (SNP) | VAF 16/494 reads (3%) | catalogued as rs1302724302; called by muse, mutect2
- DAAM1 | c.679T>C p.L227= | Silent (SNP) | VAF 165/630 reads (26%) | catalogued as rs775357562; called by muse, mutect2, varscan2
- DACT3 | c.1122C>T p.A374= | Silent (SNP) | VAF 214/629 reads (34%) | called by muse, mutect2, varscan2
- DGKI | c.2775A>G p.S925= | Silent (SNP) | VAF 46/125 reads (37%) | called by muse, mutect2, varscan2
- ECHDC3 | c.105G>A p.P35= | Silent (SNP) | VAF 205/423 reads (48%) | called by muse, mutect2, varscan2
- ERI1 | c.369T>G p.A123= | Silent (SNP) | VAF 104/104 reads (100%) | called by muse, mutect2, varscan2
- EYS | c.4168A>C p.R1390= | Silent (SNP) | VAF 130/432 reads (30%) | called by muse, mutect2
- EYS | c.3432T>A p.T1144= | Silent (SNP) | VAF 139/216 reads (64%) | catalogued as COSV101006704, COSV101007322; called by muse, mutect2, varscan2
- F13B | c.739C>T p.L247= | Silent (SNP) | VAF 77/303 reads (25%) | called by muse, mutect2, varscan2
- FBXL14 | c.216G>T p.R72= | Silent (SNP) | VAF 247/1005 reads (25%) | catalogued as COSV59335909; called by muse, mutect2, varscan2
- FKRP | c.1371C>T p.F457= | Silent (SNP) | VAF 193/600 reads (32%) | catalogued as rs1270459605, COSV59358424; called by muse, mutect2, varscan2
- GALR2 | c.876C>T p.Y292= | Silent (SNP) | VAF 209/610 reads (34%) | catalogued as rs113884061; called by muse, varscan2
- GFRAL | c.37T>C p.L13= | Silent (SNP) | VAF 116/182 reads (64%) | called by muse, mutect2, varscan2
- GRID2IP | c.2052C>T p.D684= | Silent (SNP) | VAF 200/590 reads (34%) | catalogued as rs1463331478; called by muse, varscan2
- HRNR | c.3063T>C p.S1021= | Silent (SNP) | VAF 200/564 reads (35%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.1359G>A p.R453= | Silent (SNP) | VAF 142/342 reads (42%) | called by muse, mutect2, varscan2
- KCNT2 | c.2379T>G p.T793= | Silent (SNP) | VAF 53/278 reads (19%) | called by muse, mutect2, varscan2
- KDM4D | c.633T>G p.T211= | Silent (SNP) | VAF 164/387 reads (42%) | catalogued as COSV58634067, COSV58635953; called by muse, mutect2, varscan2
- KMT2E | c.4542T>G p.T1514= | Silent (SNP) | VAF 151/309 reads (49%) | called by muse, mutect2, varscan2
- MARCHF11 | c.183C>T p.R61= | Silent (SNP) | VAF 126/243 reads (52%) | called by muse, mutect2, varscan2
- MCF2 | c.70T>C p.L24= | Silent (SNP) | VAF 93/93 reads (100%) | catalogued as COSV58476896, COSV58478333; called by muse, mutect2, varscan2
- MPZL1 | c.354A>T p.A118= | Silent (SNP) | VAF 19/345 reads (6%) | called by muse, mutect2
- MUC16 | c.7191A>G p.S2397= | Silent (SNP) | VAF 95/356 reads (27%) | catalogued as COSV67485453; called by muse, varscan2
- MUC16 | c.4050A>G p.T1350= | Silent (SNP) | VAF 134/429 reads (31%) | called by muse, mutect2, varscan2
- MYH2 | c.4992T>C p.D1664= | Silent (SNP) | VAF 99/235 reads (42%) | catalogued as rs1367186579; called by muse, mutect2, varscan2
- NKTR | c.1695A>G p.K565= | Silent (SNP) | VAF 160/472 reads (34%) | called by muse, mutect2, varscan2
- NLRP7 | c.2269A>C p.R757= (on ENST00000340844 / NM_206828.3; = p.R729= on NM_139176.3) | Silent (SNP) | VAF 166/523 reads (32%) | called by muse, mutect2, varscan2
- NPAS4 | c.1446T>A p.T482= | Silent (SNP) | VAF 184/376 reads (49%) | called by muse, mutect2, varscan2
- NPBWR1 | c.837C>T p.L279= | Silent (SNP) | VAF 419/821 reads (51%) | called by muse, mutect2, varscan2
- NRCAM | c.1332C>T p.N444= (on ENST00000379028 / NM_001371124.1; = p.N438= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 145/145 reads (100%) | catalogued as rs968424772, COSV61043856; called by muse, mutect2, varscan2
- NUP210 | c.645C>T p.S215= | Silent (SNP) | VAF 127/349 reads (36%) | called by muse, mutect2, varscan2
- OR4N2 | c.669T>C p.C223= | Silent (SNP) | VAF 133/910 reads (15%) | called by muse, mutect2, varscan2
- OSBP2 | c.2448G>A p.A816= | Silent (SNP) | VAF 297/297 reads (100%) | catalogued as rs745664497; called by muse, mutect2, varscan2
- OXTR | c.444G>A p.L148= | Silent (SNP) | VAF 189/724 reads (26%) | called by muse, mutect2, varscan2
- PCDHGA10 | c.1533C>T p.I511= | Silent (SNP) | VAF 141/409 reads (34%) | called by muse, mutect2, varscan2
- PDCD6IP | c.1698A>G p.R566= | Silent (SNP) | VAF 40/142 reads (28%) | called by muse, mutect2, varscan2
- PEX2 | c.837T>G p.T279= | Silent (SNP) | VAF 112/549 reads (20%) | called by muse, mutect2, varscan2
- PGR | c.343T>C p.L115= | Silent (SNP) | VAF 150/316 reads (47%) | catalogued as COSV54807278; called by muse, mutect2, varscan2
- PHOX2A | c.123T>A p.A41= | Silent (SNP) | VAF 254/470 reads (54%) | called by muse, mutect2, varscan2
- PON1 | c.441A>G p.Q147= | Silent (SNP) | VAF 136/475 reads (29%) | called by muse, mutect2, varscan2
- PREX2 | c.2349T>A p.A783= | Silent (SNP) | VAF 232/327 reads (71%) | catalogued as COSV55756430, COSV55778503; called by muse, mutect2, varscan2
- PUS10 | c.1107T>C p.T369= | Silent (SNP) | VAF 115/372 reads (31%) | called by muse, mutect2, varscan2
- RABGAP1 | c.1503G>A p.S501= | Silent (SNP) | VAF 66/236 reads (28%) | catalogued as rs765417210; called by muse, mutect2, varscan2
- RIMS2 | c.3702T>G p.S1234= | Silent (SNP) | VAF 207/579 reads (36%) | catalogued as COSV51664555; called by muse, mutect2, varscan2
- RORB | c.375G>A p.E125= (on ENST00000396204 / NM_001365023.1; = p.E114= on NM_006914.4) | Silent (SNP) | VAF 173/501 reads (35%) | catalogued as rs1308963406; called by muse, mutect2, varscan2
- SCN1A | c.4935A>C p.R1645= (on ENST00000303395 / NM_001202435.3; = p.R1634= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/439 reads (31%) | called by muse, mutect2, varscan2
- SKIV2L | c.2256C>G p.L752= | Silent (SNP) | VAF 79/356 reads (22%) | called by muse, mutect2, varscan2
- SLC37A2 | c.714C>T p.C238= | Silent (SNP) | VAF 148/285 reads (52%) | catalogued as rs755737985, COSV100016979; called by muse, mutect2, varscan2
- SLC4A1 | c.2604G>A p.P868= | Silent (SNP) | VAF 332/496 reads (67%) | catalogued as rs770393971; called by muse, mutect2, varscan2
- SMIM2 | c.63C>T p.G21= | Silent (SNP) | VAF 148/502 reads (29%) | called by muse, mutect2, varscan2
- SNX20 | c.507C>T p.Y169= | Silent (SNP) | VAF 192/407 reads (47%) | catalogued as rs746432403; called by muse, mutect2, varscan2
- SPOCK1 | c.669A>G p.R223= | Silent (SNP) | VAF 230/349 reads (66%) | called by muse, mutect2, varscan2
- STARD9 | c.4569T>G p.A1523= | Silent (SNP) | VAF 152/324 reads (47%) | called by muse, mutect2, varscan2
- SYNE1 | c.5067A>G p.R1689= (on ENST00000367255 / NM_182961.4; = p.R1696= on NM_033071.3) | Silent (SNP) | VAF 151/502 reads (30%) | catalogued as rs748553425; called by muse, mutect2, varscan2
- SYT10 | c.342A>G p.K114= | Silent (SNP) | VAF 284/602 reads (47%) | catalogued as COSV57338918; called by muse, mutect2, varscan2
- THBS1 | c.3006G>A p.E1002= | Silent (SNP) | VAF 117/222 reads (53%) | called by muse, mutect2, varscan2
- TRIM11 | c.492C>T p.C164= | Silent (SNP) | VAF 216/291 reads (74%) | catalogued as rs1447371557; called by muse, mutect2, varscan2
- TTN | c.19200T>G p.T6400= (on ENST00000591111; = p.T5473= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 127/422 reads (30%) | called by muse, mutect2, varscan2
- TXNDC11 | c.1539A>C p.A513= (on ENST00000356957 / NM_001303447.2; = p.A486= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/337 reads (12%) | called by muse, mutect2, varscan2
- UBQLNL | c.630A>G p.E210= | Silent (SNP) | VAF 98/202 reads (49%) | catalogued as rs781697485, COSV66494639, COSV66494802; called by muse, mutect2, varscan2
- UNC80 | c.3126C>A p.T1042= | Silent (SNP) | VAF 338/701 reads (48%) | called by muse, mutect2, varscan2
- USH2A | c.6381C>T p.G2127= | Silent (SNP) | VAF 78/339 reads (23%) | called by muse, mutect2, varscan2
- YY1AP1 | c.1854C>T p.N618= (on ENST00000295566 / NM_139118.2; = p.N561= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 166/428 reads (39%) | catalogued as rs1194530137; called by muse, mutect2, varscan2
- ZFHX4 | c.1041T>C p.H347= | Silent (SNP) | VAF 113/563 reads (20%) | catalogued as rs1348429043; called by muse, mutect2, varscan2
- ZNF276 | c.1479G>A p.V493= (on ENST00000443381 / NM_001113525.2; = p.V418= on NM_152287.4) | Silent (SNP) | VAF 90/179 reads (50%) | catalogued as rs757278617; called by muse, mutect2, varscan2
- ZNF385D | c.1110G>A p.A370= | Silent (SNP) | VAF 153/504 reads (30%) | catalogued as rs750190395; called by muse, mutect2
- ZNF606 | c.1023A>G p.G341= | Silent (SNP) | VAF 202/310 reads (65%) | called by muse, mutect2, varscan2
- ZNF606 | c.354A>G p.E118= | Silent (SNP) | VAF 151/387 reads (39%) | catalogued as COSV62049119; called by muse, mutect2, varscan2
- ZNF726 | c.1635T>C p.T545= | Silent (SNP) | VAF 157/233 reads (67%) | called by muse, mutect2, varscan2
- ZNF85 | c.438T>C p.F146= | Silent (SNP) | VAF 135/431 reads (31%) | called by muse, mutect2
- ADCYAP1R1 | c.1046+2947G>A | Intron (SNP) | VAF 128/279 reads (46%) | catalogued as rs747921046, COSV58442745; called by muse, mutect2, varscan2
- COL6A5 | c.-214C>G | 5'UTR (SNP) | VAF 185/512 reads (36%) | called by mutect2, varscan2
- DCHS2 | n.5132T>C | RNA (SNP) | VAF 177/177 reads (100%) | catalogued as COSV61768753; called by muse, mutect2, varscan2
- GRM1 | c.-1C>T | 5'UTR (SNP) | VAF 69/215 reads (32%) | catalogued as rs1393820492, COSV99263550, COSV99264718; called by muse, mutect2, varscan2
- KIR3DX1 | n.725T>G | RNA (SNP) | VAF 139/412 reads (34%) | catalogued as COSV55596745; called by muse, mutect2, varscan2
- LRP5L | n.582A>C | RNA (SNP) | VAF 134/287 reads (47%) | catalogued as COSV101292701; called by muse, mutect2, varscan2
- MSRA | c.543+17781T>A | Intron (SNP) | VAF 157/3650 reads (4%) | called by muse, mutect2
- ODF2 | c.124-344G>A | Intron (SNP) | VAF 109/413 reads (26%) | catalogued as rs142128886; called by muse, mutect2, varscan2
- RSPH9 | c.671-4355A>G | Intron (SNP) | VAF 82/291 reads (28%) | called by muse, mutect2, varscan2
- TP63 | c.325-18430G>C | Intron (SNP) | VAF 91/317 reads (29%) | catalogued as COSV99288773; called by muse, mutect2, varscan2
- TSHZ3 | c.41-28910A>T | Intron (SNP) | VAF 126/378 reads (33%) | called by muse, mutect2, varscan2
- UBE2W | chr8:73878869 A>T | 5'Flank (SNP) | VAF 318/662 reads (48%) | called by muse, mutect2, varscan2
- ZNF559 | c.243+22T>G | Intron (SNP) | VAF 120/402 reads (30%) | called by muse, varscan2
- ZNF667 | c.254-1445A>C | Intron (SNP) | VAF 92/283 reads (33%) | called by muse, mutect2, varscan2
